Gene-level copy-number profile of tumor specimen TCGA-26-1438-01A from TCGA case TCGA-26-1438, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.9 years (13,489 days).
Specimen TCGA-26-1438-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.fd039cfc-82db-4d97-b7cf-34157506b06d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-26-1438-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5fee6397-0471-4670-aa80-10ac4bc3f85d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 95; copy number 2: 7,623; copy number 3: 3,335; copy number 4: 45,525; copy number 6: 1,010; copy number 7: 58; copy number 8: 2,093; copy number 10: 1; copy number 12: 5; copy number 15: 6; copy number 16: 1; copy number 18: 23; copy number 19: 12; copy number 24: 2; copy number 26: 1; copy number 39: 18; copy number 104: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-26-1438-01): tumor purity 0.46, ploidy 2, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 79 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 16 (within-gene range 4–16): AC010983.1.
- chr5:114,576,041–114,579,970, 1 gene, copy number 10: LINC01957.
- chr12:57,253,762–57,818,704, 41 genes, copy number 18–39 (within-gene range 2–39): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4.
- chr12:59,020,169–59,054,184, 2 genes, copy number 24: RPS6P22, AC068305.1.
- chr12:59,523,278–59,789,855, 4 genes, copy number 19 (within-gene range 6–19): LINC02448, RNU4-20P, SLC16A7, AC079905.2.
- chr12:60,092,864–62,279,150, 12 genes, copy number 12–26 (within-gene range 2–26): AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19.
- chr12:62,234,390–62,600,476, 8 genes, copy number 19 (within-gene range 2–19): KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P.
- chr12:68,746,125–68,971,570, 10 genes, copy number 104: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.

Autosomal genes at a single copy (total copy number 1): 88. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
